Gene-level copy-number profile of specimen HCM-SANG-0286-C20-85A-01D-A80T-32 from HCMI case HCM-SANG-0286-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; Tumor grade: G2.
Specimen HCM-SANG-0286-C20-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 86fd8468-c72f-4edc-b91a-c1ddc58714e1.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0286-C20-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,709 have no estimate.
https://portal.gdc.cancer.gov/files/23c55960-5aa1-406d-bfbc-c7f5f5ee7f03

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 515; copy number 1: 310; copy number 2: 29,126; copy number 3: 24,587; copy number 4: 4,368; copy number 5: 7; copy number 24: 1.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:29,887,752–29,934,286, 7 genes (within-gene range 0–2): HLA-H, HLA-T, DDX39BP1, MCCD1P1, HCG4B, HLA-K, HLA-U.
- chr8:7,200,756–7,200,857, 1 gene: AF228730.1.
- chr8:8,027,077–8,040,953, 2 genes: FAM90A12P, OR7E96P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:26,686,241–26,687,964, 1 gene, copy number 24: AL513548.1.
- chr6:32,659,467–32,668,383, 2 genes, copy number 5: HLA-DQB1, HLA-DQB1-AS1.
- chr14:18,667,249–18,712,643, 5 genes, copy number 5: CR383656.3, RPL22P20, CR383656.4, CR383656.2, NF1P10.

Autosomal genes at a single copy (total copy number 1): 310. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
